Somatic mutation profile of tumor specimen MMRF_2848_1_BM_CD138pos (aliquot MMRF_2848_1_BM_CD138pos_T1_KHS5U_L16579) from MMRF case MMRF_2848, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2848_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ebb417a-d93f-4d2d-9f23-235228d9119f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2848_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2848_1_PB_WBC_C2_KHS5U_L16673; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c34074ea-176f-481e-841b-58e6e06a634b

The open-access MAF lists 141 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 37, Intron 17, Silent 15, Nonsense Mutation 5, 5'UTR 3, RNA 3, 5'Flank 2, Splice Region 2, 3'Flank 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 63/395 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as rs772496459, COSV66562165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID4A | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 9/213 reads (4%) | catalogued as COSV62165099; called by muse, mutect2
- BCL7A | c.92+1G>C p.X31_splice | Splice Site (SNP) | VAF 40/162 reads (25%) | catalogued as rs780433687, COSV55846678, COSV55850485; called by muse, mutect2, varscan2
- BGN | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1156728437, COSV59036355; called by muse, mutect2
- CADM2 | c.804A>C p.L268F (on ENST00000407528 / NM_001167674.2; = p.L270F on NM_153184.4) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101053330; called by muse, mutect2, varscan2
- CMTM5 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.151); catalogued as rs753234523, COSV100198193, COSV59305216; called by muse, mutect2, varscan2
- DISP3 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs776607837; called by muse, mutect2, varscan2
- DMTN | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs201697275; called by muse, mutect2, varscan2
- IGHV2-70 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368945949; called by muse, varscan2
- IGLV3-1 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs552062384; called by muse, varscan2
- IGLV3-1 | c.145A>T p.K49* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as rs192957059; called by muse, varscan2
- IGLV3-1 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs190667156; called by muse, varscan2
- LRP12 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs777987080; called by muse, mutect2, varscan2
- NECTIN3 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as rs1175952960, COSV60552985; called by muse, mutect2, varscan2
- PCDHA11 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV56493566; called by muse, mutect2
- RSPH4A | c.46_48del p.E16del | In Frame Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs771322050; called by pindel, varscan2
- SETD2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV57439588, COSV57442602; called by muse, mutect2, varscan2
- SPNS2 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1025178871; called by muse, mutect2
- UPF1 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53198443; called by muse, mutect2, varscan2
- ABCC5 | c.1377A>C p.E459D | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.134); called by muse, mutect2
- ACSM2B | c.491T>A p.I164N | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ADGRG6 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.095); called by muse, mutect2
- ATOH1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- BAHCC1 | c.-206A>G | Splice Region (SNP) | VAF 45/240 reads (19%) | called by muse, mutect2, varscan2
- C14orf93 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCAR2 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.901); called by muse, varscan2
- CCDC22 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC47 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2
- CHIA | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CMC1 | c.19+4C>T | Splice Region (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- COL12A1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIAPH2 | c.2480G>T p.S827I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.6837G>T p.E2279D (on ENST00000445597; = p.E2932D on NM_001367479.1) | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FAM228A | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.019); called by muse, mutect2
- FOXN1 | c.1859T>G p.F620C | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- HDAC4 | c.440A>C p.H147P | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- IGHV2-70D | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, varscan2
- IGHV2-70D | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, varscan2
- ITGA11 | c.2351A>T p.D784V | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIZ | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
- MAGEB18 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MARK2 | c.769-1G>C p.X257_splice | Splice Site (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- MATN3 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.261); called by muse, mutect2
- MGAM | c.4253G>A p.W1418* | Nonsense Mutation (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- MOK | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- MST1 | c.2173G>C p.G725R | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NKX2-6 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUDT11 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PAPOLA | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- QSOX2 | c.1918G>T p.G640W | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- RAD1 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RIPPLY2 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- RSRC2 | c.677T>G p.F226C | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SEC22B | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- SLC9A5 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ST13 | c.612T>A p.D204E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCERG1 | c.2315T>C p.L772S | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TENT5C | c.910T>A p.Y304N | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TLL1 | c.1360T>A p.F454I | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC3 | c.1114G>T p.V372L (on ENST00000379645 / NM_001366479.2; = p.V299L on NM_003305.2) | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTYH3 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- TUB | c.158A>T p.D53V (on ENST00000299506 / NM_177972.3; = p.D108V on NM_003320.4) | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CHI3L1 | c.579G>A p.K193= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV55137998; called by muse, mutect2, varscan2
- DNAAF6 | c.117T>G p.L39= | Silent (SNP) | VAF 137/299 reads (46%) | called by muse, mutect2, varscan2
- EHHADH | c.1065C>T p.G355= | Silent (SNP) | VAF 60/234 reads (26%) | catalogued as rs761606930; called by muse, mutect2, varscan2
- FRK | c.720G>A p.L240= | Silent (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.52T>C p.L18= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs782219473; called by muse, mutect2, varscan2
- IGHV2-70 | c.357A>C p.I119= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs139383686; called by muse, varscan2
- KCNC1 | c.540C>T p.F180= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV56391949; called by muse, mutect2
- KIAA0825 | c.3636C>T p.N1212= | Silent (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2
- PDE1A | c.1077C>T p.S359= | Silent (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- POGK | c.1749G>C p.L583= | Silent (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- RASA1 | c.1869C>G p.V623= | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- SLC26A6 | c.2118G>A p.A706= | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as rs200411127, COSV100258377; called by muse, mutect2, varscan2
- SLC5A8 | c.105T>G p.A35= | Silent (SNP) | VAF 42/130 reads (32%) | called by muse, mutect2, varscan2
- TTC5 | c.1098A>C p.A366= | Silent (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- UGT2B15 | c.339A>G p.L113= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs558921173; called by muse, mutect2, varscan2
- ABCC9 | c.*1501G>A | 3'UTR (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- ACACB | c.6788-380T>C | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- ALOX12B | c.650+107A>C | Intron (SNP) | VAF 48/153 reads (31%) | catalogued as rs1451694109; called by muse, mutect2, varscan2
- ANK3 | c.2738+179G>T | Intron (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.162C>A | RNA (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- BMP6 | c.*1145T>C | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CACNA2D4 | c.2922-55G>A | Intron (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- CADM2 | chr3:86068381 A>C | 3'Flank (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- CAMK4 | c.*4041A>G | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- CLVS2 | c.*429T>C | 3'UTR (SNP) | VAF 13/84 reads (15%) | catalogued as rs535216211; called by muse, mutect2, varscan2
- CTTNBP2NL | c.*511C>A | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.*3230C>T | 3'UTR (SNP) | VAF 9/46 reads (20%) | catalogued as rs1374538920; called by muse, mutect2, varscan2
- DYNLT1 | c.272-102T>C | Intron (SNP) | VAF 72/354 reads (20%) | called by muse, mutect2, varscan2
- EAPP | c.74+50C>T | Intron (SNP) | VAF 45/146 reads (31%) | catalogued as rs1245198935; called by muse, mutect2, varscan2
- ECI1 | c.*117G>A | 3'UTR (SNP) | VAF 23/78 reads (29%) | catalogued as rs915187396; called by muse, mutect2, varscan2
- EP300 | c.-183C>G | 5'UTR (SNP) | VAF 69/280 reads (25%) | called by muse, mutect2, varscan2
- EYS | c.1766+3734T>A | Intron (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- FAM199X | c.*3701T>C | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- FGFR3 | c.-90_-74del | 5'UTR (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- GBF1 | c.*86T>A | 3'UTR (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- GDF10 | c.*762A>C | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- GOT1 | c.*292G>A | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- H2AC11 | c.*247G>C | 3'UTR (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- H2BC18 | chr1:149812363 T>A | 5'Flank (SNP) | VAF 56/231 reads (24%) | called by muse, mutect2, varscan2
- HLA-DPB2 | n.80G>T | RNA (SNP) | VAF 72/406 reads (18%) | called by muse, mutect2, varscan2
- ITGA7 | chr12:55684649 A>G | 3'Flank (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*410C>A | 3'UTR (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- KLHDC7A | c.*484G>A | 3'UTR (SNP) | VAF 5/61 reads (8%) | catalogued as COSV101272879; called by muse, mutect2
- KLK14 | c.-55T>A | 5'UTR (SNP) | VAF 8/55 reads (15%) | catalogued as rs751615132; called by muse, mutect2, varscan2
- KRTAP5-4 | c.*308G>A | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- MAGT1 | c.*2680A>T | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- MAP2K6 | c.367-50T>C | Intron (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- MGAM | c.4619-13759C>T | Intron (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- MLLT6 | c.*2582dup | 3'UTR (INS) | VAF 45/147 reads (31%) | catalogued as rs1286419769; called by mutect2, pindel, varscan2
- MPPED2 | c.*1307G>A | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- NDUFS7 | c.122+95G>A | Intron (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- NELL1 | c.*631A>T | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- NFKB1 | c.*48A>G | 3'UTR (SNP) | VAF 87/417 reads (21%) | called by muse, mutect2, varscan2
- OLFML3 | c.115-78C>T | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- OXNAD1 | c.*817T>A | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- PARVA | c.*1187C>T | 3'UTR (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- PIWIL1 | c.-12-231A>C | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- PPME1 | c.554-114C>T | Intron (SNP) | VAF 15/67 reads (22%) | catalogued as rs761277731, COSV100076665; called by muse, mutect2, varscan2
- PRDM2 | c.*476C>T | 3'UTR (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.*1814A>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- RAB35 | c.*1117G>T | 3'UTR (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- RAN | chr12:130872053 G>T | 5'Flank (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- RNMT | c.*2080A>C | 3'UTR (SNP) | VAF 8/215 reads (4%) | called by muse, mutect2
- SERAC1 | c.1404-40G>A | Intron (SNP) | VAF 26/68 reads (38%) | catalogued as rs562582686; called by muse, mutect2, varscan2
- SLC35D2 | c.*161G>A | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- SLC7A1 | c.*3435G>A | 3'UTR (SNP) | VAF 56/225 reads (25%) | catalogued as rs536711225; called by muse, mutect2, varscan2
- SMAD3 | c.*1239T>C | 3'UTR (SNP) | VAF 41/119 reads (34%) | catalogued as rs1327474750; called by muse, mutect2, varscan2
- SPOCK1 | c.*1865C>T | 3'UTR (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- TBC1D22A | c.*1243G>C | 3'UTR (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- TCF3 | c.1327-9C>T | Intron (SNP) | VAF 4/54 reads (7%) | catalogued as rs985596540; called by muse, mutect2
- TECPR2 | c.3790-78C>T | Intron (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- TENM1 | c.*3770_*3773del | 3'UTR (DEL) | VAF 7/34 reads (21%) | catalogued as rs1295333655; called by pindel, varscan2
- TLE4 | c.46-113G>T | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- WDR35 | c.*1370G>A | 3'UTR (SNP) | VAF 30/62 reads (48%) | catalogued as rs1039776865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF286A | c.*2165A>C | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- ZNF561-AS1 | n.231C>T | RNA (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ZNF747 | c.*373A>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ZNF791 | c.*164C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as COSV58481098; called by muse, mutect2
- ZNF792 | c.*575G>T | 3'UTR (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
